Gene-level copy-number profile of tumor specimen TCGA-DX-A8BP-01A from TCGA case TCGA-DX-A8BP, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant fibrous histiocytoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 85.9 years (31,382 days).
Specimen TCGA-DX-A8BP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.18813cf6-aec9-47b8-8864-447f32f66a42.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A8BP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cdb1dddf-99f5-483a-b49b-7d3b6f57252a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 13,102; copy number 2: 34,961; copy number 3: 8,392; copy number 4: 2,770; copy number 5: 410; copy number 11: 86; copy number 19: 54; copy number 22: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A8BP-01A-11D-A37B-01): tumor purity 0.51, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,699,314–22,214,672, 16 genes: RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 564 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:50,396,192–60,522,120, 154 genes, copy number 11–22 (within-gene range 1–22) (broad region; genes not listed).
- chr19:1,107,637–1,780,988, 42 genes, copy number 5 (within-gene range 1–5): SBNO2, STK11, HMGB2P1, CBARP, AC004221.1, ATP5F1D, MIDN, CIRBP, CIRBP-AS1, FAM174C, EFNA2, RPS15P9, AC005330.1, PWWP3A, AC004623.1, AC005329.2, NDUFS7, AC005329.3, AC005329.1, GAMT, DAZAP1, RPS15, AC027307.3, APC2, AC027307.2, C19orf25, PCSK4, REEP6, ADAMTSL5, PLK5, AC027307.1, MEX3D, RN7SL477P, MBD3, AC005943.2, AC005943.1, UQCR11, TCF3, RNU6-1223P, Metazoa_SRP, AC005256.1, ONECUT3.
- chr20:36,507,702–50,882,676, 368 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10,721. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
